Somatic mutation profile of tumor specimen TCGA-QK-AA3J-01A (aliquot TCGA-QK-AA3J-01A-11D-A391-08) from TCGA case TCGA-QK-AA3J, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 69.7 years (25,469 days).
Specimen TCGA-QK-AA3J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0cfd2d2-f21e-40ad-8a1d-24cd0b259ab3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-AA3J-10A (Blood Derived Normal), aliquot TCGA-QK-AA3J-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4060f76b-8859-4c99-9dc4-72f18ecae87f

The open-access MAF lists 127 somatic variants for this specimen: 90 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 34, Nonsense Mutation 4, In Frame Del 3, Frame Shift Del 2, Intron 2, Splice Site 2, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.2362C>T p.R788* | Nonsense Mutation (SNP) | VAF 27/37 reads (73%) | catalogued as rs1057520339, CM052298, COSV61779938, COSV61779986; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 35/44 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 208/913 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as COSV55936434; called by muse, mutect2, varscan2
- AMBRA1 | c.1222C>T p.R408* (on ENST00000458649 / NM_001367468.1; = p.R318* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 43/73 reads (59%) | catalogued as rs967739661, COSV54049518; called by muse, mutect2, varscan2
- ANO5 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100201720; called by muse, mutect2, varscan2
- APAF1 | c.713C>T p.S238F (on ENST00000551964 / NM_181861.2; = p.S227F on NM_001160.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100452452; called by muse, mutect2, varscan2
- ARHGAP44 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV99310484; called by muse, mutect2
- BAG4 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV99781788; called by muse, mutect2, varscan2
- BANP | c.283C>T p.P95S (on ENST00000286122; = p.P103S on NM_017869.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.993); catalogued as COSV99621305; called by muse, mutect2, varscan2
- BCAS1 | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV101006138; called by muse, mutect2, varscan2
- BMP6 | c.768C>A p.F256L | Missense Mutation (SNP) | VAF 87/116 reads (75%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); catalogued as rs771409026, COSV99306709; called by muse, mutect2, varscan2
- BMT2 | c.26A>G p.N9S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV99774534; called by muse, varscan2
- BSND | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs768951289, COSV100987619; called by muse, mutect2, varscan2
- C5 | c.1496A>G p.Y499C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99797627; called by muse, mutect2, varscan2
- CATSPER1 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100375831; called by muse, mutect2, varscan2
- CBFA2T2 | c.34A>G p.I12V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV100674140; called by muse, mutect2, varscan2
- CDK1 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV100358806; called by muse, mutect2, varscan2
- CELA2A | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV100657525; called by muse, mutect2, varscan2
- CELSR2 | c.3776C>G p.S1259C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99603579; called by muse, mutect2, varscan2
- CEP192 | c.6701A>T p.Q2234L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100381009; called by muse, mutect2, varscan2
- CLCN3 | c.2276C>G p.P759R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100641661; called by muse, mutect2, varscan2
- CLTCL1 | c.3614G>A p.C1205Y | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555939483, COSV99594856; called by muse, mutect2, varscan2
- COL1A2 | c.863C>G p.P288R | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV99799289; called by muse, mutect2, varscan2
- CUL5 | c.1508C>A p.S503Y | Missense Mutation (SNP) | VAF 84/127 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101263658; called by muse, mutect2, varscan2
- CUX2 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as rs765779977, COSV55635837; called by muse, mutect2, varscan2
- DRC1 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 43/235 reads (18%) | catalogued as COSV99985254; called by muse, mutect2, varscan2
- EGFLAM | c.2945G>C p.R982T (on ENST00000354891 / NM_001205301.2; = p.R974T on NM_152403.4) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.505); catalogued as rs1178602379, COSV100380164; called by muse, mutect2, varscan2
- ELAC2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs1382116568, CM012929, COSV100568342; called by muse, mutect2, varscan2
- ELMO3 | c.2041T>C p.F681L (on ENST00000652269; = p.F628L on NM_024712.5) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100440776; called by muse, mutect2, varscan2
- FGFRL1 | c.1073-1G>A p.X358_splice | Splice Site (SNP) | VAF 24/37 reads (65%) | catalogued as COSV99294585; called by muse, mutect2, varscan2
- FLG | c.3902A>T p.Q1301L | Missense Mutation (SNP) | VAF 46/447 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100911432; called by muse, varscan2
- FLG | c.3901C>A p.Q1301K | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.286); catalogued as COSV100911433; called by muse, varscan2
- FOCAD | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100620276; called by muse, mutect2, varscan2
- FOCAD | c.4288G>C p.E1430Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.094); catalogued as COSV100620277; called by muse, mutect2, varscan2
- GREB1 | c.3373C>T p.H1125Y | Missense Mutation (SNP) | VAF 84/391 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV99302722; called by muse, mutect2, varscan2
- HNRNPU | c.258_263del p.E93_E94del | In Frame Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs772147656; called by mutect2, pindel, varscan2
- HOOK3 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as rs1468967757; called by muse, mutect2
- ILF3 | c.2330A>G p.Y777C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs962208264, COSV99139550; called by muse, mutect2, varscan2
- KIAA0100 | c.4450T>G p.S1484A | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV101197274; called by muse, mutect2, varscan2
- KIDINS220 | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.243); catalogued as COSV99875432; called by muse, mutect2, varscan2
- KLHL22 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.574); catalogued as rs761638825, COSV100185932; called by muse, mutect2, varscan2
- KRT72 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99537181; called by muse, mutect2, varscan2
- LAMB4 | c.3328T>C p.C1110R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99223586; called by muse, mutect2, varscan2
- LMTK2 | c.3268G>C p.E1090Q | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99806575; called by muse, mutect2, varscan2
- LRRC3B | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101185774; called by muse, mutect2, varscan2
- MAGEA12 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 101/135 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100756880, COSV100756901; called by muse, mutect2, varscan2
- MAP3K6 | c.1928A>G p.Y643C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371702909; called by muse, mutect2, varscan2
- MCM2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as rs190889381, COSV54035084; called by muse, mutect2, varscan2
- MTA2 | c.460C>G p.Q154E | Missense Mutation (SNP) | VAF 114/319 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99604203; called by muse, mutect2, varscan2
- MYH4 | c.3802G>A p.E1268K | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV99700966; called by muse, mutect2, varscan2
- MYO10 | c.2314A>G p.I772V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as rs975256651, COSV99945143; called by muse, mutect2, varscan2
- NUFIP2 | c.2050A>T p.I684F | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56603698, COSV99837343; called by muse, mutect2, varscan2
- OR10G8 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs761642040, COSV101461825; called by muse, mutect2, varscan2
- PCDHGA2 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.262); catalogued as rs1341781160, COSV99535516; called by muse, mutect2, varscan2
- PDE4A | c.1418A>T p.H473L (on ENST00000380702 / NM_001111307.2; = p.H234L on NM_006202.3) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99533955; called by muse, mutect2, varscan2
- PIP5K1B | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99598541; called by muse, mutect2, varscan2
- POLE | c.3273G>C p.E1091D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV57674873; called by muse, mutect2, varscan2
- PSME4 | c.5311C>T p.L1771F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV101122420; called by muse, mutect2, varscan2
- PTPRG | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs770912567, COSV99874234; called by muse, mutect2, varscan2
- PVRIG | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV52782941; called by muse, mutect2, varscan2
- RAB35 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99984564; called by muse, mutect2, varscan2
- RPS6KA4 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs773514684, COSV99589932; called by muse, mutect2, varscan2
- SAFB | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV99412684; called by muse, mutect2, varscan2
- SAMD3 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100695924; called by muse, mutect2, varscan2
- SCN7A | c.514T>A p.S172T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as COSV101313165; called by muse, mutect2, varscan2
- SMARCA4 | c.4171-2A>G p.X1391_splice | Splice Site (SNP) | VAF 32/107 reads (30%) | catalogued as COSV100758390; called by muse, mutect2, varscan2
- SMYD1 | c.528G>C p.V176= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101352418; called by muse, mutect2
- SPTB | c.6768T>G p.F2256L | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as COSV99906479; called by muse, mutect2, varscan2
- STT3B | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 88/143 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as rs779739661, COSV99854242; called by muse, mutect2, varscan2
- TAT | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1190018965, COSV100587587; called by muse, mutect2, varscan2
- TET3 | c.1136A>T p.Q379L | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as COSV99996284; called by muse, mutect2, varscan2
- TGFB2 | c.630G>C p.W210C | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100860033; called by muse, mutect2, varscan2
- TLR4 | c.1177C>G p.Q393E (on ENST00000355622 / NM_138554.5; = p.Q353E on NM_003266.4) | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100842729; called by muse, mutect2, varscan2
- TMEM248 | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100447244; called by muse, mutect2, varscan2
- TNS1 | c.3637A>T p.S1213C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV99410371; called by muse, mutect2, varscan2
- TRIM48 | c.541A>G p.I181V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV101338253; called by muse, mutect2, varscan2
- UNC5C | c.1827G>T p.M609I | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV71662802; called by muse, mutect2
- VPS13C | c.7394A>T p.E2465V (on ENST00000644861 / NM_020821.3; = p.E2422V on NM_017684.5) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs767670257, COSV99828057; called by muse, mutect2, varscan2
- VPS26A | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99697581; called by muse, mutect2, varscan2
- WDR17 | c.2212C>T p.Q738* | Nonsense Mutation (SNP) | VAF 31/97 reads (32%) | catalogued as rs371649006; called by muse, mutect2, varscan2
- YIPF4 | c.241T>A p.L81M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99479826; called by muse, mutect2, varscan2
- ZNF165 | c.1091G>C p.R364T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV101055896, COSV66103112; called by muse, mutect2, varscan2
- ZNF646 | c.4628C>T p.S1543L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99762199; called by muse, mutect2, varscan2
- ZNF780A | c.1114C>G p.L372V | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.991); catalogued as COSV100575045; called by muse, mutect2, varscan2
- COQ8B | c.847dup p.W283Lfs*4 | Frame Shift Ins (INS) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- HK2 | c.2613del p.F871Lfs*9 | Frame Shift Del (DEL) | VAF 203/456 reads (45%) | called by mutect2, pindel, varscan2
- IGLV3-12 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SERPINF1 | c.853_867del p.N285_I289del | In Frame Del (DEL) | VAF 92/160 reads (58%) | called by mutect2, pindel, varscan2
- ZNF57 | c.1121_1131del p.T374Nfs*3 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1515_1517del p.H505del | In Frame Del (DEL) | VAF 18/72 reads (25%) | called by pindel, varscan2
- ABCB1 | c.3195G>A p.T1065= | Silent (SNP) | VAF 142/185 reads (77%) | catalogued as rs368096241; ClinVar: drug response; called by muse, mutect2, varscan2
- COL6A3 | c.2250C>T p.L750= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs761079155, COSV99797453; called by muse, mutect2, varscan2
- DEFB110 | c.91T>C p.L31= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV64484853; called by muse, mutect2, varscan2
- GABRQ | c.1548G>A p.G516= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV100941196; called by muse, mutect2, varscan2
- H2BC15 | c.348C>G p.T116= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV57586251; called by muse, mutect2, varscan2
- KCNT1 | c.1419C>G p.L473= (on ENST00000488444; = p.L492= on NM_020822.3) | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99705523; called by muse, varscan2
- KIAA1522 | c.2367C>T p.A789= (on ENST00000373480 / NM_001198972.2; = p.A848= on NM_020888.3) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99614461; called by muse, mutect2, varscan2
- MAB21L2 | c.360G>A p.S120= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as rs146043387, COSV58263166; called by muse, mutect2, varscan2
- MKRN1 | c.1185C>T p.G395= | Silent (SNP) | VAF 70/131 reads (53%) | catalogued as rs775485297, COSV55436124; called by muse, mutect2, varscan2
- MTIF2 | c.1159C>T p.L387= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV99709072; called by muse, mutect2, varscan2
- MYBL2 | c.426G>A p.E142= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV53832495, COSV99406211; called by muse, mutect2, varscan2
- OR4A47 | c.543C>G p.P181= | Silent (SNP) | VAF 79/318 reads (25%) | catalogued as rs1222575556, COSV71445010; called by muse, mutect2, varscan2
- OR4C15 | c.222T>C p.N74= (on ENST00000314644; = p.N20= on NM_001001920.2) | Silent (SNP) | VAF 58/162 reads (36%) | catalogued as COSV100115574; called by muse, mutect2, varscan2
- PCDH9 | c.219C>A p.A73= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100119701; called by muse, mutect2, varscan2
- PCLO | c.630T>C p.P210= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100430520; called by muse, mutect2, varscan2
- PIP4P2 | c.471T>C p.C157= | Silent (SNP) | VAF 64/199 reads (32%) | catalogued as rs1423821488, COSV99575267; called by muse, mutect2, varscan2
- PRIMPOL | c.732A>G p.T244= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs1450699518, COSV100153100; called by muse, mutect2, varscan2
- PSAP | c.507C>G p.A169= | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as COSV101206480; called by muse, mutect2, varscan2
- PTGER2 | c.825C>T p.V275= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99817419; called by muse, mutect2, varscan2
- RET | c.2574C>T p.I858= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV100393179; called by muse, mutect2, varscan2
- RHBDL3 | c.1074G>A p.L358= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV99283640; called by muse, mutect2, varscan2
- RPS25 | c.291C>T p.I97= | Silent (SNP) | VAF 50/85 reads (59%) | catalogued as COSV100548699; called by muse, mutect2, varscan2
- SAMD9L | c.2400C>A p.L800= | Silent (SNP) | VAF 45/234 reads (19%) | catalogued as COSV100560586; called by muse, mutect2, varscan2
- SEC24B | c.2469G>A p.L823= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99493252; called by muse, mutect2, varscan2
- SIK3 | c.879G>T p.V293= (on ENST00000445177 / NM_001366686.2; = p.V299= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV99407583; called by muse, mutect2, varscan2
- SLFN13 | c.1428C>G p.L476= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV53193236; called by muse, mutect2, varscan2
- TRAF7 | c.1824C>T p.I608= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100399370; called by muse, mutect2, varscan2
- TRAPPC8 | c.4236G>A p.S1412= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs745390603, COSV99350971; called by muse, mutect2, varscan2
- UGT1A4 | c.498G>A p.S166= | Silent (SNP) | VAF 103/275 reads (37%) | catalogued as rs368511777, COSV59399365; called by muse, mutect2, varscan2
- USH2A | c.9411T>C p.N3137= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV56336765; called by muse, mutect2, varscan2
- WNK3 | c.3795C>T p.S1265= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV100671162; called by muse, mutect2, varscan2
- WRN | c.615C>A p.L205= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as COSV99988790; called by muse, mutect2, varscan2
- ZNF133 | c.1962C>T p.L654= (on ENST00000316358 / NM_001352454.2; = p.L653= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV100315409; called by muse, mutect2
- ZNF385B | c.1224G>T p.R408= | Silent (SNP) | VAF 48/234 reads (21%) | catalogued as COSV100415949; called by muse, mutect2, varscan2
- CCDC140 | n.843A>G | RNA (SNP) | VAF 10/18 reads (56%) | catalogued as rs1256893249, COSV99735059; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7905G>A | Intron (SNP) | VAF 36/102 reads (35%) | catalogued as rs565662180, COSV100875854; called by muse, mutect2, varscan2
- NCL | c.898+66T>G | Intron (SNP) | VAF 47/152 reads (31%) | catalogued as COSV100502302; called by muse, mutect2, varscan2
